TCGA case TCGA-2H-A9GR — Esophageal Carcinoma (TCGA-ESCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus; Tissue source site: Erasmus MC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e9aa4430-0203-413c-a8fe-bb89e95cf6a3

Demographics
Sex at birth: male; Country of residence at enrollment: Netherlands; Age at index: 80 years; Vital status: Dead; Days to death: 987 days (2.7 years).

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C15.5; Tissue or organ of origin: Lower third of esophagus; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 80.6 years (29,451 days); Year of diagnosis: 1999; Method of diagnosis: Surgical Resection; AJCC staging edition: 5th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Cancer detection method: Symptomatic; Esophageal columnar dysplasia degree: High Grade Dysplasia; Esophageal columnar metaplasia present: Yes; Sites of involvement: Esophagus, Lower Third.
   Pathology details: Consistent pathology review: Yes; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 3.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 987 days (2.7 years); Disease response: With Tumor.
- Follow-up contact recording only the day: prior to diagnosis.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 67 kg; Height: 168 cm; BMI: 23.7.
- Timepoint category: Prior to Diagnosis; Comorbidities: Barrett's Esophagus; Risk factors: Barrett's Esophagus.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2H-A9GR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 110 mg.
  Slide TCGA-2H-A9GR-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-2H-A9GR-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2H-A9GR-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 90 mg.
  Slide TCGA-2H-A9GR-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Cancer procurement state province: ZH; Cancer procurement city: Rotterdam; History neoadjuvant treatment: No; Tumor status: With tumor; Alcohol history documented: No; History barretts esophageal indicator: Yes-UK.
- Primary pathology: Esophageal tumor location centered: Distal; Histologic diagnosis: Esophagus Adenocarcinoma, NOS; Method initial path diagnosis: Other method, specify:; Lymph node sprd radiograph evidence: No; Lymph nodes examined: Yes.
- Primary pathology, Esophageal tumor involvement sites: Esophageal tumor location involved: Distal.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 987 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 987 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 987 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-2H-A9GR-01A-12D-A37B-01): tumor purity 0.58, ploidy 1.9, whole-genome doublings 0.
